MMRF case MMRF_2081 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3d5ebf3f-0cbd-458a-820d-65652e9682d7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.4 years (25,353 days); ISS stage: I; Days to last known disease status: 901 days (2.5 years); Days to last follow up: 901 days (2.5 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 179 days; Days to treatment end: 179 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 180 days; Days to treatment end: 180 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 0): M Protein 0.92 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.046 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 269 mg/dL; Immunoglobulin G 3.63 g/L; Immunoglobulin A 10.9 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.58 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 5.28 mmol/L; C-Reactive Protein 0.03 mg/dL.
- Day 99 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.692 mg/dL; Immunoglobulin G 4.17 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 471 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.55 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 6 mmol/L.
- Day 212 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.651 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 5.24 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 4.18 mmol/L.
- Day 262 (ECOG 1): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.144 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 6.52 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.03 µg/mL; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 10.9 ×10⁹/L; Absolute Neutrophil 9.8 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 5.8 g/dL; Glucose 6 mmol/L.
- Day 344 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.796 mg/dL; Immunoglobulin G 5.16 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 1.34 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 415 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.763 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 5.28 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 4.4 mmol/L.
- Day 537 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.566 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.664 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 6.05 mmol/L.
- Day 621 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.626 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.814 mg/dL; Immunoglobulin G 9.92 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 7.43 mmol/L.
- Day 726: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.796 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 4.68 mmol/L.
- Day 809: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.671 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.862 mg/dL; Immunoglobulin G 7.05 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.5 g/L; Lactate Dehydrogenase 4.2 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 4.62 mmol/L.
- Day 901 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.654 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.866 mg/dL; Immunoglobulin G 5.39 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 4.68 mmol/L.

Other clinical attributes
- Day -4: Weight: 58 kg; Height: 150 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2081_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2081_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
